Surgical pathology report (de-identified scan), TCGA case TCGA-DU-7018, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Henry Ford Hospital, specimen TCGA-DU-7018-01A (Primary Tumor).

[page 1 of 3]
=====

CLINICAL HISTORY

_____ woman has right frontal brain tumor detected in
_____ and
currently has papilledema and large irregularly enhancing tumor with
midline
shift.

OPERATIVE DIAGNOSES

Not Given

Operation/Specimen: A: Right frontal tumor
B: Right frontal tumor

PATHOLOGICAL DIAGNOSIS:

A and B. Brain, right frontal, excision: Anaplastic
oligodendroglioma.
See Comment.

COMMENT

Parts A and B contain portions of an oligodendroglioma. The neoplasm
has
focal cellular anaplasia, mitotic figures, microvascular
proliferation, and
one zone of necrosis. There are karyorrhectic tumor cells throughout,
and
occasionally in vessels. In part B there is one focal area of
extensive
hyalinization, probably in vessels that become confluent. There is
also focal
mineralization
Special stains to better characterize the tumor are being requested
and will
be reported as an addendum.

Electronically Signed Out

=====

[page 2 of 3]
PROCEDURES/ADDENDA

MGMT Promoter Methylation

Date Ordered: [REDACTED]

Interpretation

POSITIVE - Methylated MGMT promoter is detected.

Results-Comments

Submitted were paraffin curls labeled

TEST DESCRIPTION: Bisulfite treatment of DNA followed by PCR amplification of both methylated and unmethylated MGMT promoter sequences, with products detected by gel electrophoresis.

FDA COMMENT: The above data are not to be construed as the results from a stand-alone diagnostic test. This test was developed and its performance characteristics determined by the AP Molecular Pathology laboratory as required by CLIA ' regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Immunohistology

Date Ordered: [REDACTED]

Interpretation

Brain, immunohistochemistry: MIB-1 proliferation index .
See Results and Comment.

Results-Comments

IMMUNOHISTOCHEMISTRY: The GFAP demonstrates very sparse gliofibrillarity in the background, which focally is synaptophysin positive, interpreted as evidence of the infiltrative character of the neoplasm. The neoplastic cells do not over express the p53 protein. With the MIB-1 there is a proliferation index of about 20% in the more active areas. The Neu N (from the Hermelin Brain Tumor Center), a neuronal marker, depicts a few positive nuclei, focally.
Comment: The immunophenotype is consistent with a high histological grade

[page 3 of 3]
oligodendroglioma. There may be a very minor component of neuronal elements, as may be observed in some oligodendrogliomas. The diagnosis remains as anaplastic oligodendroglioma.

=====

INTRA-OPERATIVE CONSULTATION

Right frontal tumor, touch preps and smears: Glioma (C/W oligodendroglioma, anaplastic). Part A. [REDACTED]

[REDACTED], Senior Staff Pathologist

GROSS DESCRIPTION

A.

Received fresh, two fragments, 0.5-cm. across in aggregate. Soft, grayish-brown, glistening. In total, A1.

B.

SPECIMEN: Right frontal tumor.

FIXATIVE: None.

GENERAL: Several fragments of pink-tan rubbery soft tissue, 0.9 gm pink-tan

rubbery soft tissue fragment, 2.5 x 1 x 0.5 cm in aggregate.

SECTIONS: B1 and B2 all submitted

[REDACTED]

ICD-9(s):

191.9 191.9

[REDACTED]

Histo Data

Part A: Right frontal tumor

Taken: [REDACTED]

Stain/cnt	Block	Ordered	Comment
mGFAP-DA x 1	1	[REDACTED]	
H/E x 1	1	[REDACTED]	
MGMT x 1	1	[REDACTED]	
MIB1-DA x 1	1	[REDACTED]	
P53DO7 x 1	1	[REDACTED]	
Synap-DA x 1	1	[REDACTED]	

Part B: Right frontal tumor

Taken: [REDACTED]

Stain/cnt	Block	Ordered	Comment
H/E x 1	1	[REDACTED]	
H/E x 1	2	[REDACTED]	
Synap-DA x 1	2	[REDACTED]	

*** End of Report ***

Source: NCI Genomic Data Commons file a586566f-4d2e-4e57-ae47-2319f14171fe (TCGA-DU-7018.CAA41707-CB2E-4C3F-BAE9-DDF6B21D5D4F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).